CCDI case PBCIRC — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/18596221-c881-4f9b-8208-48738f4b942f

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Neoplasm, malignant: ICD-O-3 morphology code: 8000/3; Tissue or organ of origin: Overlapping lesion of brain and central nervous system; Age at diagnosis: 9.7 years (3,542 days).

Biospecimens (3 samples)
- Sample 0DT3U9: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DT3UC: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DT3UR: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
